Somatic mutation profile of tumor specimen HCM-CSHL-0584-C19-06A (aliquot HCM-CSHL-0584-C19-06A-11D-A82H-36) from HCMI case HCM-CSHL-0584-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.7 years (21,437 days).
Specimen HCM-CSHL-0584-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f08cad8-9b13-48ac-9cb0-97b395a7208a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0584-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0584-C19-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6502a113-5f86-4fe4-9600-c0c93c6b94c8

The open-access MAF lists 86 somatic variants for this specimen: 63 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 21, Nonsense Mutation 9, 3'UTR 1, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs397516265, CM116379; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 414/526 reads (79%) | hotspot (GDC flag); catalogued as rs876658483, COSV52774899; ClinVar: pathogenic; called by muse, mutect2
- CACNG2 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 164/398 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as rs1164294842; called by muse, mutect2, varscan2
- CALCR | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as rs763907185, COSV64006591; called by muse, mutect2, varscan2
- CDK12 | c.2651A>G p.Y884C | Missense Mutation (SNP) | VAF 134/192 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200264056; called by muse, mutect2, varscan2
- CLSTN1 | c.2362C>T p.R788W (on ENST00000377298 / NM_001009566.3; = p.R778W on NM_014944.4) | Missense Mutation (SNP) | VAF 146/422 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1270731621, COSV100790796, COSV63650552; called by muse, mutect2, varscan2
- COL22A1 | c.1586A>G p.K529R | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as rs1227955647; called by muse, varscan2
- ENOX1 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 235/598 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs200537425, COSV99816059; called by muse, mutect2, varscan2
- FLRT2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1256512394; called by muse, varscan2
- FOXF2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 311/740 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1163121584; called by muse, mutect2, varscan2
- FOXJ1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 478/647 reads (74%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1015321881; called by muse, mutect2, varscan2
- GLB1L2 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 117/554 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV60277497; called by muse, mutect2, varscan2
- HLA-DQB1 | c.207C>A p.Y69* | Nonsense Mutation (SNP) | VAF 111/259 reads (43%) | catalogued as rs767838386; called by muse, mutect2
- LRP2 | c.11206C>T p.R3736C | Missense Mutation (SNP) | VAF 89/383 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275575465, COSV55544664; called by muse, mutect2, varscan2
- MAP7D1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 291/780 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs761765823; called by muse, mutect2, varscan2
- NEU4 | c.1183C>T p.R395C (on ENST00000391969 / NM_001167602.3; = p.R407C on NM_080741.4) | Missense Mutation (SNP) | VAF 316/1107 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.431); catalogued as rs758309387; called by muse, mutect2, varscan2
- OR8B12 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747843848, COSV60911636; called by muse, mutect2, varscan2
- PAN3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 113/245 reads (46%) | catalogued as COSV56700966; called by muse, mutect2, varscan2
- PEX6 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 127/615 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs757254854, COSV55105777; called by muse, mutect2, varscan2
- PIGU | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.179); catalogued as rs1205128943; called by muse, mutect2
- RBM10 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 140/247 reads (57%) | catalogued as COSV61308429; called by muse, mutect2, varscan2
- RBM48 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 112/418 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as rs369894722; called by muse, varscan2
- RNF40 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 96/593 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs1180838040; called by muse, mutect2, varscan2
- SCN4A | c.4358C>G p.A1453G | Missense Mutation (SNP) | VAF 190/526 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV71127091; called by muse, mutect2, varscan2
- SELPLG | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 184/484 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as rs145775085; called by muse, mutect2, varscan2
- SLC16A6 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555749415; called by muse, mutect2, varscan2
- STX11 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 246/658 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV62449182, COSV62449325; called by muse, mutect2, varscan2
- TCERG1L | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 148/423 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV64046565; called by muse, mutect2
- TEPSIN | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 326/428 reads (76%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as rs779349589, COSV56142254; called by muse, mutect2, varscan2
- TKFC | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 155/595 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs144053132; called by muse, mutect2, varscan2
- TTN | c.21396A>C p.Q7132H (on ENST00000591111; = p.Q6205H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/334 reads (23%) | PolyPhen benign (0); catalogued as COSV60190155; called by muse, mutect2, varscan2
- ZAN | c.3540C>A p.Y1180* | Nonsense Mutation (SNP) | VAF 119/497 reads (24%) | catalogued as rs1447501376; called by muse, mutect2, varscan2
- ACAP1 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 163/479 reads (34%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- APC | c.2719_2724del p.G907_S908del | In Frame Del (DEL) | VAF 153/250 reads (61%) | called by mutect2, pindel, varscan2
- ASB15 | c.1711A>T p.R571* | Nonsense Mutation (SNP) | VAF 90/303 reads (30%) | called by muse, mutect2, varscan2
- CEACAM18 | c.1086T>A p.N362K | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA10 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 148/486 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COX5A | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 49/284 reads (17%) | called by muse, mutect2, varscan2
- CTSZ | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 102/3440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CTTNBP2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 109/395 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHA4 | c.1280A>C p.D427A | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, varscan2
- EPHB3 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 398/689 reads (58%) | called by muse, mutect2, varscan2
- FAT3 | c.3205G>T p.D1069Y | Missense Mutation (SNP) | VAF 198/359 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO42 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- FLG | c.2497G>T p.A833S | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GIT2 | c.51G>A p.P17= | Splice Region (SNP) | VAF 18/590 reads (3%) | called by muse, mutect2
- GOLGA6D | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 70/111 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GPR83 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 99/427 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRID2IP | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 159/756 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFT81 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAML | c.312A>T p.Q104H (on ENST00000356289 / NM_001098526.2; = p.Q94H on NM_153206.3) | Missense Mutation (SNP) | VAF 114/493 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK6 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 263/717 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LCORL | c.3541A>C p.N1181H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- LHFPL6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 179/993 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MAGI2 | c.3088C>A p.Q1030K | Missense Mutation (SNP) | VAF 464/887 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCKSL1 | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 175/417 reads (42%) | called by muse, mutect2, varscan2
- MLPH | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MRPL15 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 166/711 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MTURN | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PKHD1 | c.2918T>C p.V973A | Missense Mutation (SNP) | VAF 254/602 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SHC3 | c.1374T>G p.D458E | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- SPC25 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYCP2 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACOT13 | c.240C>T p.P80= | Silent (SNP) | VAF 86/484 reads (18%) | catalogued as rs1187443661; called by muse, mutect2, varscan2
- ADCY8 | c.2388T>C p.N796= | Silent (SNP) | VAF 275/333 reads (83%) | called by muse, varscan2
- ADGRA1 | c.474C>T p.Y158= | Silent (SNP) | VAF 107/375 reads (29%) | catalogued as rs759608334, COSV66926921; called by muse, mutect2
- AHNAK | c.14091C>T p.I4697= | Silent (SNP) | VAF 122/436 reads (28%) | catalogued as rs375130667; called by muse, mutect2, varscan2
- AMFR | c.1869C>T p.T623= | Silent (SNP) | VAF 260/599 reads (43%) | catalogued as COSV51924089; called by muse, mutect2, varscan2
- CNGB3 | c.1515G>A p.T505= | Silent (SNP) | VAF 295/349 reads (85%) | catalogued as rs751667290, COSV60684314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL1 | c.1101G>A p.T367= | Silent (SNP) | VAF 271/662 reads (41%) | catalogued as rs775371452; called by muse, mutect2, varscan2
- EHD2 | c.1494C>T p.D498= | Silent (SNP) | VAF 249/619 reads (40%) | catalogued as rs570148430, COSV54409637; called by muse, mutect2, varscan2
- IL1R1 | c.1401A>C p.S467= | Silent (SNP) | VAF 83/332 reads (25%) | catalogued as COSV52106020; called by muse, mutect2, varscan2
- KCNA4 | c.492C>T p.G164= | Silent (SNP) | VAF 277/522 reads (53%) | catalogued as rs1342472405, COSV100068461; called by muse, mutect2, varscan2
- KLK4 | c.381C>T p.S127= | Silent (SNP) | VAF 158/417 reads (38%) | catalogued as COSV60676672; called by muse, mutect2, varscan2
- LRFN3 | c.363A>G p.S121= | Silent (SNP) | VAF 420/546 reads (77%) | called by muse, mutect2, varscan2
- METTL21C | c.189C>T p.Y63= | Silent (SNP) | VAF 92/568 reads (16%) | catalogued as rs140891650; called by muse, mutect2, varscan2
- MRPS21 | c.75C>T p.T25= | Silent (SNP) | VAF 73/225 reads (32%) | catalogued as COSV100481679; called by muse, mutect2, varscan2
- MYO16 | c.4371G>A p.P1457= | Silent (SNP) | VAF 1492/1717 reads (87%) | called by muse, mutect2, varscan2
- PUF60 | c.1512C>T p.G504= (on ENST00000526683 / NM_001362896.2; = p.G487= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 715/860 reads (83%) | catalogued as rs1466383479; called by muse, mutect2, varscan2
- SHROOM4 | c.582G>A p.S194= | Silent (SNP) | VAF 198/337 reads (59%) | catalogued as rs370371137; called by muse, mutect2, varscan2
- TACC3 | c.810C>T p.G270= | Silent (SNP) | VAF 20/626 reads (3%) | catalogued as rs1277292847; called by muse, mutect2
- TXLNA | c.1371G>A p.L457= | Silent (SNP) | VAF 122/316 reads (39%) | catalogued as rs1157453723; called by muse, mutect2, varscan2
- USP29 | c.1131A>G p.L377= | Silent (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.9G>A p.L3= | Silent (SNP) | VAF 87/273 reads (32%) | called by muse, mutect2, varscan2
- JUP | c.*14+104C>T | Intron (SNP) | VAF 387/489 reads (79%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1326A>C | 3'UTR (SNP) | VAF 93/277 reads (34%) | called by muse, mutect2, varscan2
